Surgical pathology report (de-identified scan), TCGA case TCGA-32-5222, project TCGA-GBM (Glioblastoma Multiforme), tissue source site St. Joseph's Hospital (AZ), specimen TCGA-32-5222-01A (Primary Tumor).

NEUROPATHOLOGY REPORT

SPECIMEN SOURCE:

1. Right temporal brain tumor
2. Right temporal brain tumor

GBM

Normal

CLINICAL DIAGNOSIS:

Right temporal brain tumor

GROSS DESCRIPTION:

1. Received fresh for frozen section are two tan soft tissues measuring 0.3 x 0.3 x 0.2 cm each. A smear is performed and the specimen is entirely frozen on one chuck.

FROZEN SECTION DIAGNOSIS:

HIGH GRADE GLIOMA CONSISTENT WITH GLIOBLASTOMA.

Tissue submitted for frozen is subsequently submitted for permanent.

2. Received in formalin labeled with the patient's name and "right temporal brain tumor" are multiple fragments of tan and tan-white soft tissue aggregating to 4.3 x 2.5 x 1.0 cm. Representative sections accounting for approximately 70% of the total specimen are submitted in three cassettes.

MICROSCOPIC DESCRIPTION:

1-2. Sections from permanent and frozen section demonstrate a markedly hypercellular glial neoplasm composed of pleomorphic cells with variable amounts of cytoplasm. The nuclei are hypochromatic with irregular nuclear contours and coarse chromatin. Twenty-one mitoses are seen per 10 high power fields. The neoplastic cells diffusely infiltrate the surrounding white matter. Microvascular proliferations are observed. Focal areas of pseudopalisading necrosis are seen.

DIAGNOSIS:

- 1-2. RIGHT TEMPORAL BRAIN TUMOR, BIOPSY AND RESECTION:
GLIOBLASTOMA.

Source: NCI Genomic Data Commons file e078b429-6026-46f1-bdcf-b027d415e0d8 (TCGA-32-5222.880E75F5-D2EC-4990-8397-3BDC9EA20693.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).